TCGA case TCGA-D3-A1Q1 — Skin Cutaneous Melanoma (TCGA-SKCM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Nevi and Melanomas; Primary site: Lymph nodes; Tissue source site: MD Anderson. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/8c54fcfd-999f-43c5-b31f-26d006f5fff3

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 79 years; Vital status: Dead; Days to death: 504 days (1.4 years).

Diagnoses (9)
1. Malignant melanoma, NOS (the primary disease): ICD-O-3 morphology code: 8720/3; ICD-10 code: C77.9; Tissue or organ of origin: Skin, NOS; Site of resection or biopsy: Lymph node, NOS; Classification of tumor: Progression; Age at diagnosis: 80.0 years (29,215 days); Days to diagnosis: 3 days; Prior treatment: No.
   Recorded as not given: Pharmaceutical Therapy, NOS, prior to procurement; Radiation Therapy, NOS, prior to procurement.
2. Malignant melanoma, NOS: ICD-O-3 morphology code: 8720/3; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 80.0 years (29,212 days); Year of diagnosis: 2004; AJCC staging edition: 7th; AJCC pathologic T: T1b; AJCC pathologic N: N3; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIIC; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Melanoma known primary: Yes.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Immunotherapy (Including Vaccines); Therapeutic agents: Antineoplastic Vaccine + Clinical Trial Agent; Days to treatment start: 247 days; Days to treatment end: 341 days; Treatment outcome: Progressive Disease; Clinical trial indicator: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide; Days to treatment start: 247 days; Days to treatment end: 341 days; Treatment outcome: Progressive Disease; Clinical trial indicator: Yes.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
3. Malignant melanoma, NOS: Tissue or organ of origin: Skin, NOS; Classification of tumor: primary; Clark level: II; Sites of involvement: Skin, Extremities; Ulceration indicator: No.
   Pathology details: Breslow thickness category: <=1 mm.
   Recorded as not given: Radiation Therapy, NOS.
4. Recurrence of diagnosis 2 (Malignant melanoma, NOS). Age at diagnosis: 80.1 years (29,270 days); Days to diagnosis: 58 days; Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Recurrent Disease; Days to treatment start: 58 days.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Radiation Therapy, NOS, for recurrent disease.
5. Recurrence of diagnosis 2 (Malignant melanoma, NOS). Age at diagnosis: 80.8 years (29,501 days); Days to diagnosis: 289 days; Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Recurrent Disease; Days to treatment start: 308 days.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Radiation Therapy, NOS, for recurrent disease.
6. Metastasis of diagnosis 2 (Malignant melanoma, NOS), site: Lymph node, NOS. Age at diagnosis: 81.0 years (29,569 days); Days to diagnosis: 357 days; Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Radiation Therapy, NOS, for progressive disease; Surgery, NOS, for progressive disease.
7. Metastasis of diagnosis 2 (Malignant melanoma, NOS), site: Connective, subcutaneous and other soft tissues of abdomen. Age at diagnosis: 81.3 years (29,681 days); Days to diagnosis: 469 days (1.3 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Progressive Disease; Days to treatment start: 471 days (1.3 years).
   Recorded as not given: Pharmaceutical Therapy, NOS, for progressive disease; Radiation Therapy, NOS, for progressive disease.
8. Metastasis of diagnosis 2 (Malignant melanoma, NOS), site: Liver. Age at diagnosis: 81.3 years (29,681 days); Days to diagnosis: 469 days (1.3 years); Prior treatment: Yes.
   Recorded as not given: Pharmaceutical Therapy, NOS, for progressive disease; Radiation Therapy, NOS, for progressive disease; Surgery, NOS, for progressive disease.
9. Metastasis of diagnosis 2 (Malignant melanoma, NOS), site: Lymph nodes of inguinal region or leg. Age at diagnosis: 81.3 years (29,681 days); Days to diagnosis: 469 days (1.3 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Progressive Disease; Days to treatment start: 471 days (1.3 years).
   Recorded as not given: Pharmaceutical Therapy, NOS, for progressive disease; Radiation Therapy, NOS, for progressive disease.

Follow-up (7 entries)
- Day 58 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Days to recurrence: 58 days.
- Day 289 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Days to recurrence: 289 days.
- Day 357 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Regional; Progression or recurrence anatomic site: Lymph node, NOS; Days to progression: 357 days.
- Day 469 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Connective, subcutaneous and other soft tissues of abdomen; Days to progression: 469 days (1.3 years).
- Day 469 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Liver; Days to progression: 469 days (1.3 years).
- Day 469 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Lymph nodes of inguinal region or leg; Days to progression: 469 days (1.3 years).
- Days to follow up: 504 days (1.4 years); Disease response: With Tumor.

Molecular and laboratory tests
- Test: Mitotic Count Reported; Mitotic count: 3.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 59 kg; Height: 162 cm; BMI: 22.5.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-D3-A1Q1-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT; Initial weight: 120 mg.
  Slide TCGA-D3-A1Q1-06A-02-TSB: Section location: Top; Percent tumor cells: 85; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 1; Percent stromal cells: 14; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 1.
- Sample TCGA-D3-A1Q1-06Z: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-D3-A1Q1-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: With tumor; Breslow thickness at diagnosis: 0.4; Primary melanoma tumor ulceration: No; Primary melanoma mitotic rate: 3; Radiation therapy to primary: No; Days from index date to submitted tumor diagnosis: 3; Primary location: Regional Lymph Node; Primary melanoma skin type: Non-glabrous skin; Prior radiation therapy: No; History neoadjuvant treatment: No.
- Sites of primary melanomas: Primary multiple at diagnosis: No.
- Sites of primary melanomas, Site: Submitted tumor site: Extremities; Melanoma primary count: 1.
- Drug treatment 1: Treatment best response: Clinical Progressive Disease.
- Drug treatment 2: Clinical trial drug classification: Melanoma-derived helper peptides; Treatment best response: Clinical Progressive Disease.
- Drug treatment 3: Clinical trial drug classification: Class I MHC restricted peptide based vaccine; Treatment best response: Clinical Progressive Disease.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 504 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 504 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 58 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-D3-A1Q1-06A-21D-A194-01): tumor purity 0.97, ploidy 3.3, whole-genome doublings 1.
